TCGA case TCGA-TS-A7P8 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Pennsylvania. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/92c1f122-2f48-47a7-b3b8-c1792a1f4f32

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Dead; Days to death: 457 days (1.3 years).

Diagnoses (2)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 80.7 years (29,464 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Porfimer Sodium; Days to treatment start: 61 days; Days to treatment end: 64 days; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 81.5 years (29,765 days); Days to diagnosis: 301 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 301 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Follow-up contact recording only the day: day 457.

Exposures
- Occupation type: Electrotechnology Engineers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-TS-A7P8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-TS-A7P8-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-TS-A7P8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-TS-A7P8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; History asbestos exposure: No; Primary occupation: Other, please specify; Occupation primary: Electrical Engineer; New tumor event diagnosis indicator: Yes.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- New tumor event: New tumor event site other: Ipsilateral Chest Cavity.
- Drug treatment: Pharmaceutical therapy drug name: Porfimer Sodium (Photofin).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 457 days; disease-specific survival: event status not recorded, 457 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 301 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-TS-A7P8-01A-11D-A34B-01): tumor purity 0.67, ploidy 2, whole-genome doublings 0.
